Somatic mutation profile of tumor specimen TCGA-V4-A9E9-01A (aliquot TCGA-V4-A9E9-01A-11D-A39W-08) from TCGA case TCGA-V4-A9E9, project TCGA-UVM (Uveal Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Spindle cell melanoma, NOS; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 50.3 years (18,387 days).
Specimen TCGA-V4-A9E9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 154151d6-50d4-471b-ae34-19c780987182.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V4-A9E9-10A (Blood Derived Normal), aliquot TCGA-V4-A9E9-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a6e613d1-35b4-454a-88c8-e3b42136521d

The open-access MAF lists 12 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 9, Silent 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAQ | c.626A>C p.Q209P | Missense Mutation (SNP) | VAF 49/112 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121913492, COSV54105903, COSV54105914, COSV54108414; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SF3B1 | c.1874G>A p.R625H | Missense Mutation (SNP) | VAF 22/58 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519961, COSV59205431, COSV59206122, COSV59206364; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS10 | c.1651G>T p.G551W | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99546603; called by muse, mutect2, varscan2
- CENPE | c.5463G>C p.K1821N | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV99477638; called by muse, mutect2, varscan2
- HASPIN | c.1472G>C p.G491A | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99561621; called by muse, mutect2, varscan2
- ZNF484 | c.2281T>G p.S761A | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV100214823; called by muse, mutect2, varscan2
- ADD1 | c.80G>C p.R27P | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- C20orf96 | c.569_570del p.L190Rfs*12 (on ENST00000360321 / NM_153269.3; = p.L189Rfs*12 on NM_080571.1) | Frame Shift Del (DEL) | VAF 77/203 reads (38%) | called by mutect2, pindel, varscan2
- CDHR1 | c.203C>T p.S68F | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- DNAJC1 | c.1142C>G p.S381C | Missense Mutation (SNP) | VAF 65/129 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- CSMD3 | c.2055T>A p.V685= (on ENST00000297405 / NM_001363185.1; = p.V581= on NM_052900.3) | Silent (SNP) | VAF 75/271 reads (28%) | called by muse, mutect2, varscan2
- GP2 | c.939C>A p.I313= (on ENST00000381362 / NM_001007240.3; = p.I310= on NM_001502.4) | Silent (SNP) | VAF 86/171 reads (50%) | catalogued as rs768974673, COSV56892363; called by muse, mutect2, varscan2
